CCDI case PBBXHB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b385a35f-0898-4820-84c3-a7f311b84095

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 10.1 years (3,673 days).

Biospecimens (3 samples)
- Sample 0DJVOY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJVP9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJVPN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
